Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7007, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7007-01A (Primary Tumor).

[page 1 of 3]
OLIGODENDROGLIOMA
DIAGNOSIS

PATHOLOGICAL DIAGNOSIS:

BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSIES: GEMISTOCYTIC ASTROCYTOMA.
SEE MICROSCOPIC DESCRIPTION AND COMMENT.

ADDENDUM DIAGNOSIS: SPECIAL STAIN REPORT: MIB-1 LABELLING INDEX 2.5%

SECOND ADDENDUM DIAGNOSIS;

2. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY: GEMISTOCYTIC ASTROCYTOMA
WITH FOCAL OLIGODENDROGLIOMA.

3. BRAIN, RIGHT FRONTAL LOBE, LOBECTOMY: MIXED GLIOMA,
OLIGOASTROCYTOMA WITH GEMISTOCYTIC FEATURES. MIB-1 LABELLING INDEX
8.0%.

SEE SECOND ADDENDUM MICROSCOPY AND COMMENT.

Operation/Specimen:

Clinical History and Pre-Op Dx: [REDACTED] with history of
headaches and seizures. On imaging studies, there is a large focally
enhancing mass with two cystic spaces in the right frontal lobe.

GROSS PATHOLOGY: Right frontal mass. Received fresh, three
fragments,

1.3 cm across in aggregate. Semi-firm, tannish-pink, in toto #1-3.

INTRAOPERATIVE CONSULTATION: Brain, right frontal: Gemistocytic
astrocytoma.

MICROSCOPIC: Portions of a cellular neoplastic proliferation of
glial
cells with over 90% exhibiting a gemistocytic phenotype. There is
very
prominent nuclear pleomorphism with some multinucleated cells. Some
vessels are cuffed by lymphoplasmacytic cells. There are no mitoses,
macrovascular cellular proliferation or necrosis.

COMMENT: This is a gemistocytic astrocytoma in which over 95% of the
cells have plump phenotype. The tumor has very prominent nuclear
atypia; however, other features of anaplasia such as mitotic figures,

[page 2 of 3]
microvascular cellular proliferation or necrosis are absent.

A MIB-1 immunoperoxidase stain is requested and a complementary report will follow.

ADDENDUM REPORT:

Special stain: A MIB-1 immunoperoxidase stain was performed on block #3.

A MIB-1 labeling index of 2.5% was determined.

SECOND ADDENDUM REPORT

Part 2 "Right frontal mass," is a discoid portion of grayish-white semi-firm tissue, 3.5 x 2.5 x 1 cm. Representative (50%) sections, #1 and 2.

Part 3 "Right frontal lobe," is a portion of cerebrum; 7 x 5.5 x 3.2 cm. On the convexity and 3 cm from 1 margin of resection, there is a reddish discoloration. A sagittal section at this level discloses hemorrhage and softening of tissue about 2.5 cm in diameter. The entire specimen is firm and the cut surfaces are grayish-white.

SLIDE KEY:

- 3 - central lesion.
- 4 - remaining lesion extending to margin.
- 5 - lateral margins.
- 6,7 - deeper margins.
- 8,9,10 - sagittal sections of central lesion.
- 11 - coronal section, deep margin.
- 12,13 - deep lateral margins.

MICROSCOPIC DESCRIPTION:

2. Portions of cerebral cortex and white mater extensively infiltrated by a neoplasm with morphological features similar to those described for the previous specimen. However in less infiltrated areas of the cortex, where abundant neuropil is still identifiable, the neoplastic cells display naked round nuclei, not infrequently surrounded by a clear halo. Mitotic figures are difficult to be identified, and microvascular cellular proliferation or necrosis are absent.

3. Sections from the central nodular portion of the lesion demonstrate focal areas with a frank astrocytic phenotype next to nodular areas of oligodendroglioma made-up of tumor cells with large, hyperchromatic nuclei surrounded by halos and well defined cell membranes. In the central area of the specimen, there are irregularly shaped cystic spaces surrounded by rarified white matter with neoplastic glial cells and focal secretion of mucinous material. These spaces become confluent and form larger cysts. The entire specimen is permeated throughout by neoplastic cells with oligodendroglial characteristics, usually with some preservation of the neuropil or white matter,

[page 3 of 3]
occasionally with formation of nodules. In relationship with the more cellular areas, there are vessels cuffed by mononuclear inflammatory cells, which are seen permeating the wall of some of these vessels. Mitotic figures are difficult to be found, and areas of microvascular cellular proliferation or necrosis are absent. The tumor is present in all margins of resection.

SPECIAL STAINS: MIB-1 immunoperoxidase stain was performed on blocks 1 and 8. A MIB-1 labelling index of 1% was determined on block #8 representing the bulk of the neoplasm. A labelling index of 8% was determined in one focal hypercellular area, block #1.

COMMENT: The lesion is a mixed glioma with an epicenter containing areas of gemistocytic astrocytoma and oligodendroglioma, which surround portions of rarified white matter with sparsely infiltrating neoplasm that have become cystic and confluent. From the epicenter, the tumor is observed infiltrating the cerebral cortex and white matter as individual cells with oligodendrocyte morphology and varying cellularity. Neoplastic infiltration is reaching all margins of resection. In the more cellular areas of tumor, there are perivascular lymphocytic infiltrates. In spite of the focal prominent cellularity and nuclear pleomorphism, mitotic figures are rare and microvascular cellular proliferation or areas of necrosis are absent.

In this tumor, the oligodendroglioma is the predominant component, and it is of low grade [REDACTED] [REDACTED]. However, the gemistocytic component and the focal MIB-1 labelling index of 8% are worrisome, as they probably portend aggressive behavior.

Source: NCI Genomic Data Commons file 7f6d64a7-cd73-4d0a-a5e5-44aacec4522e (TCGA-DU-7007.FFBBE732-9A5A-4269-B0A7-99F993906030.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).